Somatic mutation profile of cancer-model specimen HCM-BROD-0694-C43-85N (Adherent Cell Line, passage 9; aliquot HCM-BROD-0694-C43-85N-01D-A83U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0694-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 45.9 years (16,765 days).
Specimen HCM-BROD-0694-C43-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab8f5c4a-559e-4951-a44a-99ac0ef1c526.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0694-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0694-C43-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37875561-35c1-4f1e-9ae0-3ed39a68f207

The open-access MAF lists 49 somatic variants for this specimen: 27 protein-altering or splice-affecting, 18 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 18, Intron 2, Nonsense Mutation 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C16orf96 | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 24/826 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as rs1180533213; called by muse, mutect2
- COL6A6 | c.880C>T p.Q294* | Nonsense Mutation (SNP) | VAF 11/391 reads (3%) | catalogued as COSV62031799; called by muse, mutect2
- FBXO10 | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 30/992 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs1251656148, COSV52834959; called by muse, mutect2
- GAREM1 | c.1064A>G p.K355R | Missense Mutation (SNP) | VAF 55/803 reads (7%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.985); catalogued as rs1020968458; called by muse, mutect2
- ITGB4 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 12/486 reads (2%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs886053409, COSV52322502, COSV52324788, COSV52332573; ClinVar: uncertain significance; called by muse, mutect2
- KIF26A | c.69G>T p.E23D | Missense Mutation (SNP) | VAF 111/985 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.739); catalogued as COSV59465560; called by muse, mutect2, varscan2
- LLGL2 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 104/993 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs1235682339; called by muse, mutect2, varscan2
- OR2AK2 | c.845C>A p.T282K | Missense Mutation (SNP) | VAF 41/436 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV100823769; called by muse, mutect2
- OR52E6 | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 15/580 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs1428334209, COSV61431747, COSV61432662; called by muse, mutect2
- SPOCD1 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 92/887 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs555926182, COSV57095318, COSV57097256; called by muse, mutect2, varscan2
- ZNF425 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 66/648 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs750605283, COSV65202792; called by muse, mutect2, varscan2
- ATP8B2 | c.2875C>G p.Q959E (on ENST00000672630; = p.Q926E on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/295 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BICD1 | c.2693C>T p.P898L | Missense Mutation (SNP) | VAF 17/653 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- CAMTA1 | c.797G>A p.G266D | Missense Mutation (SNP) | VAF 22/877 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.11); called by muse, mutect2
- CHEK2 | c.1127T>G p.L376W (on ENST00000382580 / NM_001005735.2; = p.L333W on NM_007194.4) | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); called by muse, mutect2
- DENND4A | c.551A>T p.N184I | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); called by muse, varscan2
- DSP | c.5461G>T p.V1821F | Missense Mutation (SNP) | VAF 27/482 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.168); called by muse, mutect2
- HUNK | c.808C>G p.L270V | Missense Mutation (SNP) | VAF 84/795 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- MYO18B | c.2678A>T p.D893V | Missense Mutation (SNP) | VAF 14/451 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.369); called by muse, mutect2
- SLC16A14 | c.196C>T p.H66Y | Missense Mutation (SNP) | VAF 25/865 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.26); called by muse, mutect2
- SLC22A7 | c.557G>A p.G186D (on ENST00000372585 / NM_153320.2; = p.G184D on NM_006672.3) | Missense Mutation (SNP) | VAF 32/1163 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2
- SLC7A13 | c.262T>A p.F88I | Missense Mutation (SNP) | VAF 22/712 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.248); called by muse, mutect2
- TRAM2 | c.695G>T p.R232I | Missense Mutation (SNP) | VAF 86/716 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- TRAV12-3 | c.171G>T p.W57C | Missense Mutation (SNP) | VAF 14/401 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRPC7 | c.2318C>G p.T773S | Missense Mutation (SNP) | VAF 21/329 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- USP17L2 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 12/484 reads (2%) | SIFT tolerated (0.14); PolyPhen benign (0.16); called by muse, mutect2
- YIPF7 | c.717T>G p.I239M | Missense Mutation (SNP) | VAF 13/467 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- ABCC5 | c.2199G>A p.K733= | Silent (SNP) | VAF 61/675 reads (9%) | catalogued as rs1192870443; called by muse, mutect2
- AKAP6 | c.1914G>A p.K638= | Silent (SNP) | VAF 28/445 reads (6%) | catalogued as rs764315751; called by muse, mutect2
- ANO6 | c.25T>C p.L9= | Silent (SNP) | VAF 40/832 reads (5%) | catalogued as rs1484288376; called by muse, mutect2
- C16orf96 | c.1986C>T p.A662= | Silent (SNP) | VAF 24/823 reads (3%) | called by muse, mutect2
- CDH6 | c.804C>T p.F268= | Silent (SNP) | VAF 16/559 reads (3%) | called by muse, mutect2
- CPT1C | c.1074G>A p.L358= | Silent (SNP) | VAF 32/1104 reads (3%) | catalogued as rs1174977117; called by muse, mutect2
- DDR1 | c.18G>A p.L6= | Silent (SNP) | VAF 32/1210 reads (3%) | called by muse, mutect2
- ETS2 | c.1326C>T p.F442= | Silent (SNP) | VAF 31/1046 reads (3%) | catalogued as COSV62872282; called by muse, mutect2
- FAT4 | c.13146G>A p.G4382= | Silent (SNP) | VAF 16/483 reads (3%) | catalogued as rs925363038, COSV100630546; called by muse, mutect2
- MGAM2 | c.2352G>A p.R784= | Silent (SNP) | VAF 17/182 reads (9%) | called by muse, mutect2
- NKTR | c.4273C>A p.R1425= | Silent (SNP) | VAF 20/636 reads (3%) | called by muse, mutect2
- PCDHA2 | c.168G>A p.L56= | Silent (SNP) | VAF 32/1246 reads (3%) | called by muse, mutect2
- POM121L2 | c.1335G>A p.G445= | Silent (SNP) | VAF 31/1006 reads (3%) | called by muse, mutect2
- PRDM9 | c.678G>A p.K226= | Silent (SNP) | VAF 46/1106 reads (4%) | called by muse, mutect2
- RTL1 | c.2718C>T p.Y906= | Silent (SNP) | VAF 97/1088 reads (9%) | called by muse, mutect2
- SLC4A5 | c.669C>T p.P223= | Silent (SNP) | VAF 21/850 reads (2%) | called by muse, mutect2
- TPO | c.2253G>A p.G751= | Silent (SNP) | VAF 38/1130 reads (3%) | catalogued as rs1169165027; called by muse, mutect2
- TULP1 | c.651G>A p.R217= | Silent (SNP) | VAF 27/978 reads (3%) | called by muse, mutect2
- AL353804.4 | chrX:73822253 T>C | 5'Flank (SNP) | VAF 22/241 reads (9%) | called by muse, mutect2
- CEP95 | c.367+52T>C | Intron (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- KCNQ1 | c.1394-19148C>T | Intron (SNP) | VAF 9/112 reads (8%) | called by muse, mutect2
- MFSD4B | c.*771A>G | 3'UTR (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
